FM case AD7519 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Ureter.
https://portal.gdc.cancer.gov/cases/bf22e0e5-0627-4413-a583-935aef0bc78f

Male, 68.5 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the ureter; metastasis biopsied or resected from the urethra. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
